Somatic mutation profile of tumor specimen TCGA-FE-A235-01A (aliquot TCGA-FE-A235-01A-11D-A16O-08) from TCGA case TCGA-FE-A235, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 27.0 years (9,859 days).
Specimen TCGA-FE-A235-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e4634fc-cc83-49f4-af7f-6cdab8299568.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FE-A235-10A (Blood Derived Normal), aliquot TCGA-FE-A235-10A-01D-A16O-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/246486bf-15a0-4643-a0f9-6a022ffa870d

The open-access MAF lists 13 somatic variants for this specimen: 12 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 8, Frame Shift Del 2, Nonstop Mutation 1, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- DCAF12L2 | c.1001C>T p.P334L | Missense Mutation (SNP) | VAF 53/139 reads (38%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1229366218, COSV63580270, COSV63581169; called by muse, mutect2, varscan2
- IARS1 | c.1309C>G p.P437A | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65116834; called by muse, mutect2
- KCNN3 | c.613G>A p.G205S | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT tolerated (0.86); PolyPhen benign (0.023); catalogued as COSV55225070; called by muse, mutect2, varscan2
- NPR1 | c.2291G>A p.R764Q | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs751951729, COSV64118048; called by muse, mutect2, varscan2
- PHF6 | c.277G>T p.G93C | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59705991; called by muse, mutect2
- PRDM9 | c.1565C>T p.A522V | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as COSV57011967; called by muse, mutect2
- TMPRSS11F | c.298C>T p.R100* | Nonsense Mutation (SNP) | VAF 11/29 reads (38%) | catalogued as rs542655796, COSV62464715; called by muse, mutect2, varscan2
- APOA4 | c.35del p.L12Rfs*19 | Frame Shift Del (DEL) | VAF 89/245 reads (36%) | called by mutect2, pindel, varscan2
- CASP10 | c.1566G>T p.*522Yext*16 | Nonstop Mutation (SNP) | VAF 10/192 reads (5%) | called by muse, mutect2
- CGB1 | c.76C>T p.R26W | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2
- SLC22A2 | c.1126_1127del p.I376Lfs*11 | Frame Shift Del (DEL) | VAF 35/98 reads (36%) | called by pindel, varscan2
- CACNA1G | c.4164G>A p.P1388= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as rs527581833, COSV61736317; called by muse, mutect2, varscan2
